Somatic mutation profile of tumor specimen MP2PRT-PAUTJG-TMP1-A (aliquot MP2PRT-PAUTJG-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUTJG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,431 days).
Specimen MP2PRT-PAUTJG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16b8159f-9403-4b34-83a6-561f7a3f6035.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUTJG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUTJG-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/615141f4-8ab3-4835-a571-dc96bf71a02b

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 13, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730880471; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ATP8A1 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as rs372573029; called by muse, mutect2, varscan2
- CDH23 | c.2174C>T p.S725L | Missense Mutation (SNP) | VAF 106/246 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1242750822; called by muse, mutect2, varscan2
- CYP2A13 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 138/308 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.347); catalogued as rs745670637, COSV57836833; called by muse, mutect2, varscan2
- DSG3 | c.2560A>T p.K854* | Nonsense Mutation (SNP) | VAF 113/301 reads (38%) | catalogued as rs552614590, COSV57124258; called by muse, mutect2, varscan2
- FLG | c.9958C>T p.R3320C | Missense Mutation (SNP) | VAF 195/526 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770664817, COSV64239791; called by muse, mutect2, varscan2
- AMOT | c.1984G>A p.E662K (on ENST00000371959 / NM_001113490.1; = p.E253K on NM_133265.3) | Missense Mutation (SNP) | VAF 70/469 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARTN | c.427G>C p.E143Q (on ENST00000372354; = p.E151Q on NM_057090.2) | Missense Mutation (SNP) | VAF 178/431 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ATR | c.6260T>A p.M2087K | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- DCT | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DIDO1 | c.5584G>A p.E1862K | Missense Mutation (SNP) | VAF 198/489 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- EPHA6 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 54/415 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ETV6 | c.1180dup p.M394Nfs*32 | Frame Shift Ins (INS) | VAF 84/287 reads (29%) | called by mutect2, pindel, varscan2
- PDE3B | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PLCL1 | c.2884G>C p.D962H | Missense Mutation (SNP) | VAF 18/363 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); called by muse, mutect2
- KLF9 | c.27C>T p.F9= | Silent (SNP) | VAF 154/380 reads (41%) | called by muse, mutect2, varscan2
- SQSTM1 | c.1005T>C p.D335= | Silent (SNP) | VAF 124/304 reads (41%) | catalogued as rs1274935409, CM0910349; called by muse, mutect2, varscan2
